Somatic mutation profile of tumor specimen BA2041D (aliquot aq-BA2041D) from BEATAML1.0 case 2121, project BEATAML1.0-COHORT (Functional Genomic Landscape of Acute Myeloid Leukemia). Sex at birth: female; Vital status: Alive; Primary diagnosis: Acute myeloid leukemia, NOS; Tissue or organ of origin: Bone marrow; Age at diagnosis: 32.8 years (11,982 days).
Specimen BA2041D: Sample type: Primary Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Bone Marrow NOS; Preservation method: Snap Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 0f95e79f-2c96-4976-8e4b-f4a0f195a031.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen BA2862D (Solid Tissue Normal), aliquot aq-BA2862D; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/ff14dfb7-a8ae-444a-8389-f189dfbb1f86

The open-access MAF lists 14 somatic variants for this specimen: 7 protein-altering or splice-affecting, 2 silent, 5 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 6, Intron 3, Silent 2, RNA 1, 3'Flank 1, Frame Shift Del 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- PTPN11 | c.179G>C p.G60A | Missense Mutation (SNP) | VAF 24/179 reads (13%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.953); catalogued as rs397507509, CD041931, CM021126, CX060726, COSV100692385, COSV61005028, COSV61006397; ClinVar: pathogenic; called by muse, mutect2, varscan2
- DIAPH2 | c.3224G>A p.R1075Q | Missense Mutation (SNP) | VAF 46/101 reads (46%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.992); catalogued as rs771338255, COSV100230461, COSV61266215; called by muse, mutect2, varscan2
- MAP1B | c.5842C>T p.R1948W | Missense Mutation (SNP) | VAF 68/206 reads (33%) | SIFT deleterious (0); PolyPhen possibly damaging (0.548); catalogued as rs151255965; called by muse, mutect2
- PCDHGA1 | c.1276G>A p.D426N | Missense Mutation (SNP) | VAF 134/344 reads (39%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (1); catalogued as COSV65300583; called by muse, mutect2, varscan2
- KCNK12 | c.979G>T p.A327S | Missense Mutation (SNP) | VAF 3/34 reads (9%) | SIFT tolerated (0.52); PolyPhen benign (0.005); called by muse, mutect2
- RPAP2 | c.1105G>A p.V369I | Missense Mutation (SNP) | VAF 37/114 reads (32%) | SIFT tolerated (0.06); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- UBTF | c.1333_1339del p.W445Tfs*63 | Frame Shift Del (DEL) | VAF 54/113 reads (48%) | called by mutect2, pindel*, varscan2
- PLPPR4 | c.2133C>T p.S711= | Silent (SNP) | VAF 28/138 reads (20%) | catalogued as COSV64565324, COSV64565634; called by muse, mutect2, varscan2
- RCN3 | c.627G>A p.L209= | Silent (SNP) | VAF 20/42 reads (48%) | called by muse, varscan2
- ADGRG2 | c.305-45C>T | Intron (SNP) | VAF 34/89 reads (38%) | catalogued as rs371601163; called by muse, mutect2, varscan2
- AHSA2P | n.1693C>T | RNA (SNP) | VAF 55/168 reads (33%) | called by muse, mutect2, varscan2
- DEPDC4 | c.879-1127C>A | Intron (SNP) | VAF 50/162 reads (31%) | called by muse, mutect2, varscan2
- PPFIBP2 | chr11:7656764 G>A | 3'Flank (SNP) | VAF 39/233 reads (17%) | catalogued as rs966674148; called by muse, mutect2, varscan2
- WAC | c.1289-416C>T | Intron (SNP) | VAF 87/213 reads (41%) | called by muse, mutect2, varscan2
